CCDI case PBCDFP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/da5fd6e6-9ebf-4f34-9005-b257b13bcba7

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.5 years (1,628 days).

Biospecimens (2 samples)
- Sample 0DP4P5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP4Q8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
